CCDI case PBBKLS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/f03ed033-56df-4b0e-9b25-ae61ac8d2d80

Demographics
Sex at birth: male; Race: native hawaiian or other pacific islander.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 16.6 years (6,049 days).

Biospecimens (2 samples)
- Sample 0DB2AM: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DB2B9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
